Gene-level copy-number profile of tumor specimen TCGA-X7-A8D7-01A from TCGA case TCGA-X7-A8D7, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 47.0 years (17,161 days).
Specimen TCGA-X7-A8D7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.40e15093-95f7-4c94-979e-222a36daf685.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X7-A8D7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f75b84d-3778-44bf-a866-7f5b3d36c40e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 58; copy number 2: 59,755.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X7-A8D7-01A-11D-A422-01): tumor purity 0.25, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,300,322, 7 genes (within-gene range 0–2): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
